Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A48F, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A48F-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN INFORMATION

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Prostate:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 5.5 x 4.8 x 4.5 cm, 51.3 grams.
3. Tumor quantitation: Neoplasm involves 85% of the prostate gland examined.
4. Gleason grade:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 8/10.
5. Extraprostatic extension: No.
6. Seminal vesicle involvement: No.
7. Lymphovascular space invasion: Present.
8. High grade PIN: Present.
9. Treatment effect: Not applicable.

Surgical Margin Status:

1. Sections of the base of the prostate gland demonstrate presence of adenocarcinoma at the inked margin.

Lymph Node Status:

1. See specimen B below.

B. Bilateral pelvic lymph nodes:

Total number of lymph nodes examined: 10.

Total number of lymph nodes containing metastatic carcinoma: 1.

Size of the metastasis: Less than 0.1 cm.

Neoplasm is confined to the subcapsular sinus and does not extend into perinodal adipose tissue.

pTNM Stage: pT2c, N1, MX.

ICD-O3

CqCF: adenocarcinoma, acinar
8550/3

Path: adenocarcinoma, NOS
8140/3

Site: prostate, NOS
C61.9

9-7-12
12D

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm prostate, prostate for tissue study

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Prostate

B. Bilateral pelvic lymph nodes

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers labeled with the patient's name

A. Container A is additionally labeled Prostate and contains a 51.3 gram, 5.5 x 4.8 x 4.5 cm prostate received with attached bilateral adnexa having overall dimensions of 4.0 x 3.5 x 0.7 cm. The capsule is purple-gray and shaggy. The capsule is inked black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a pink-tan focally cystic cut surface with diffuse periurethral nodularity. Discrete cysts are not identified. Representative sections are submitted in cassettes A1-A18 labeled designated as follows: 1. Right prostate/seminal vesicle junction; 2. Left prostate/seminal vesicle junction; 3 and 4. Apical margin, perpendicular, and 5. Base of margin, perpendicular; 7-10. Right anterior, apex to base; 10-12. Right posterior, apex to base; 13-15. Left anterior, apex to base; 16-18. Left posterior, apex to base. Additionally, a yellow and green cassette are submitted for genomics research each labeled

[page 2 of 2]
B. Container B is additionally labeled Bilateral pelvic lymph nodes and contains a 7.0 x 6.0 x 2.0 cm aggregate of yellow-tan lobulated fibroadipose tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.5 up to 4.0 cm in greatest dimension. They are entirely submitted in cassettes B1-7 labeled as follows: B1. Five whole possible lymph nodes; B2. Two whole possible lymph nodes; B3 and 4. One whole possible bisected lymph node in each cassette; B5-7. One whole possible quadrisectioned lymph node.

Reviewed/Initialed:	Date Reviewed: 8/30/12	

hw
8/30/12

Source: NCI Genomic Data Commons file 18bffdbb-336a-42ab-ac88-47c5e21af142 (TCGA-HC-A48F.0886739D-01AE-43B1-9898-F1AB30BA940C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).